Gene-level copy-number profile of tumor specimen ALCH-B0AM-TTP1-A from ALCHEMIST case ALCH-B0AM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,702 days).
Specimen ALCH-B0AM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe10538f-46d3-403e-a3fa-f58326d01da5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0AM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/3e516b65-10c7-4cc7-98dc-a9f0be8a877f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 9,168; copy number 2: 42,501; copy number 3: 6,692; copy number 4: 246; copy number 5: 148; copy number 6: 33; copy number 7: 35; copy number 8: 3; copy number 9: 31; copy number 10: 33; copy number 11: 18; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:5,132,749–5,133,229, 1 gene: BOD1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 303 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:602,620–4,866,311, 73 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr5:4,775,476–9,546,075, 82 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr5:13,250,235–13,250,662, 1 gene, copy number 6: RPS23P5.
- chr5:34,651,457–40,269,719, 92 genes, copy number 5 (broad region; genes not listed).
- chr10:34,109,560–34,815,325, 1 gene, copy number 5 (within-gene range 4–5): PARD3.
- chr10:34,488,583–35,698,037, 27 genes, copy number 5–6: ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37.
- chr20:19,212,642–19,722,926, 1 gene, copy number 5 (within-gene range 1–5): SLC24A3.
- chr20:19,242,302–20,360,703, 12 genes, copy number 5 (within-gene range 1–5): SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1.
- chr20:64,049,836–64,327,972, 14 genes, copy number 7: TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 6,319. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
